Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040031-09A.4 (aliquot TARGET-15-SJMPAL040031-09A.4-01D) from TARGET case TARGET-15-SJMPAL040031, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,054 days).
Specimen TARGET-15-SJMPAL040031-09A.4: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35889d04-3a53-447f-9f8a-5099b0bd00ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040031-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040031-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99e7c185-ed8c-4d08-849a-62d2a029cdbb

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 67/172 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HEATR5B | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, varscan2
- IGHV1-69 | chr14:106714664 GTGGGTTTTCACACTGTGTCTCTCGCA>ATGAGCTTTCACACTGTGTCATCC | Missense Mutation (DEL) | VAF 5/44 reads (11%) | called by pindel, varscan2*
- MCEMP1 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2
- SRSF2 | c.497_498insGCCC p.R167Pfs*49 | Frame Shift Ins (INS) | VAF 22/48 reads (46%) | called by pindel, varscan2
- PPP1R26 | c.2151G>A p.A717= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs527358949; called by muse, varscan2
- SPRR2B | c.189C>T p.C63= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1035683029, COSV58797405; called by muse, mutect2, varscan2
